Somatic mutation profile of tumor specimen TCGA-X7-A8DE-01A (aliquot TCGA-X7-A8DE-01A-11D-A423-09) from TCGA case TCGA-X7-A8DE, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 35.5 years (12,957 days).
Specimen TCGA-X7-A8DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f521f2f2-5516-4c0e-b624-6dcfbaa3efde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DE-10A (Blood Derived Normal), aliquot TCGA-X7-A8DE-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c49e60b5-9ca6-4835-842c-01fdddd6e5cd

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 36/632 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- ABCA2 | c.5897A>T p.K1966M (on ENST00000614293; = p.K1936M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); called by muse, varscan2
- MAP2K2 | c.178_192del p.Q60_V64del | In Frame Del (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
- PGAP1 | c.1200C>T p.C400= | Silent (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
